Somatic mutation profile of tumor specimen TCGA-AP-A05P-01A (aliquot TCGA-AP-A05P-01A-11W-A062-09) from TCGA case TCGA-AP-A05P, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 54.8 years (20,017 days).
Specimen TCGA-AP-A05P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a311a4b-a939-4cc9-85fd-cf2754c1542b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05P-10A (Blood Derived Normal), aliquot TCGA-AP-A05P-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9acb7d41-3516-42b0-a8a5-614a54be0fe7

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Nonsense Mutation 6, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- AMBRA1 | c.3875G>A p.R1292K (on ENST00000458649 / NM_001367468.1; = p.R1202K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV54057534; called by muse, mutect2, varscan2
- ATP2B2 | c.1265C>T p.T422M (on ENST00000352432; = p.T388M on NM_001683.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770734675, COSV59500521; called by muse, mutect2, varscan2
- BTBD11 | c.2050G>A p.E684K (on ENST00000280758 / NM_001018072.2; = p.E221K on NM_001017523.2) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs147351765, COSV55025977; called by muse, mutect2, varscan2
- CASP8 | c.722A>G p.N241S (on ENST00000432109 / NM_033355.3; = p.N258S on NM_001228.4) | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1360228191, COSV51852774, COSV51853857; called by muse, mutect2
- CYP11A1 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51433016; called by muse, mutect2, varscan2
- DIP2A | c.4556A>G p.N1519S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.056); catalogued as COSV59480794; called by muse, mutect2, varscan2
- DZIP1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV61267083; called by muse, mutect2
- EEF2K | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs1315933393, COSV53779688; called by muse, mutect2
- EPX | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs781059184, COSV56597231; called by muse, mutect2, varscan2
- GALNT2 | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795542, COSV64195990; called by muse, mutect2, varscan2
- GLP1R | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1189829779, COSV100952612, COSV64714124; called by muse, mutect2, varscan2
- GRIA1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777000021, COSV53590416; called by muse, mutect2
- GRK4 | c.1030C>T p.R344* (on ENST00000398052 / NM_182982.3; = p.R312* on NM_005307.3) | Nonsense Mutation (SNP) | VAF 12/115 reads (10%) | catalogued as rs760891038, COSV61668476; called by muse, mutect2, varscan2
- IFT172 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 80/948 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144890293; called by muse, mutect2
- KCNV1 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.727); catalogued as COSV52087061; called by muse, mutect2, varscan2
- KIF26B | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV68572507; called by muse, mutect2, varscan2
- MAGEB6B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1456844558; called by muse, mutect2, varscan2
- OR8G2P | c.504G>T p.L168F | Missense Mutation (SNP) | VAF 134/576 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775181786; called by muse, mutect2
- PCDHB6 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV50704903; called by muse, mutect2, varscan2
- PPFIA1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 123/533 reads (23%) | catalogued as COSV54132518; called by muse, mutect2, varscan2
- PTEN | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV64289872, COSV64299283; called by muse, mutect2
- RB1 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57306860; called by muse, mutect2, varscan2
- RERE | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV61944968; called by muse, mutect2, varscan2
- RNF128 | c.977G>A p.G326E (on ENST00000255499 / NM_194463.2; = p.G300E on NM_024539.3) | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55252321; called by muse, mutect2
- SH3BP4 | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60644624; called by muse, mutect2, varscan2
- SLITRK5 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1312648845, COSV61523892, COSV61527514; called by muse, mutect2
- TCTE1 | c.651G>T p.E217D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as COSV65255866; called by muse, mutect2, varscan2
- TFDP1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs751799043, COSV64739677; called by muse, mutect2, varscan2
- TIAM2 | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 49/192 reads (26%) | catalogued as rs370100446, COSV59697191; called by muse, mutect2, varscan2
- TMEM207 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 43/189 reads (23%) | catalogued as COSV61561561; called by muse, mutect2, varscan2
- TNFRSF19 | c.116T>G p.F39C | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50315412; called by muse, mutect2, varscan2
- TNFRSF19 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 15/283 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV50315449; called by muse, mutect2
- TRMT9B | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1246395584, COSV71600481; called by muse, mutect2
- TRO | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV51503624; called by muse, mutect2, varscan2
- TTN | c.13022C>T p.T4341I (on ENST00000591111; = p.T4295I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as rs758799742, COSV60164238; called by muse, mutect2
- UGT2B17 | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 104/468 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58502021; called by muse, mutect2, varscan2
- USP16 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57626344; called by muse, mutect2, varscan2
- GJB1 | c.477C>A p.G159= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV62139737; called by muse, mutect2, varscan2
- GRM6 | c.1221G>A p.A407= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs544297690, COSV51432864, COSV99179554; called by muse, mutect2, varscan2
- HCN1 | c.2361C>T p.S787= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs758609806, COSV57510971; called by muse, mutect2, varscan2
- HTR3E | c.153A>G p.R51= (on ENST00000415389 / NM_001256613.1; = p.R66= on NM_182589.2) | Silent (SNP) | VAF 76/326 reads (23%) | catalogued as COSV58947564; called by muse, mutect2, varscan2
- MYO7B | c.3288C>T p.I1096= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs376503815, COSV67351043; called by muse, mutect2, varscan2
- NEURL1 | c.186G>A p.P62= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs147011641; called by muse, mutect2, varscan2
- NLRP4 | c.1293G>A p.A431= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs1320712119, COSV56717029; called by muse, mutect2, varscan2
- PCDHA9 | c.1671C>T p.D557= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV65323757; called by muse, mutect2, varscan2
- RNASE11 | c.333C>T p.N111= | Silent (SNP) | VAF 24/298 reads (8%) | catalogued as rs759244231, COSV60087902; called by muse, mutect2
- SACS | c.5409G>A p.K1803= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as COSV66542763; called by muse, mutect2
- UTP20 | c.6363C>T p.C2121= | Silent (SNP) | VAF 24/320 reads (8%) | catalogued as rs926510854, COSV55379963; called by muse, mutect2
- CYBB | c.-2C>A | 5'UTR (SNP) | VAF 17/186 reads (9%) | catalogued as COSV101059669; called by muse, mutect2
- THRA | c.1110+76C>T | Intron (SNP) | VAF 19/81 reads (23%) | catalogued as COSV52844437; called by muse, mutect2, varscan2
- TPT1 | c.517-134G>A | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as rs1290581617, COSV58538962; called by muse, mutect2, varscan2
